Gene-level copy-number profile of tumor specimen TCGA-94-A5I6-01A from TCGA case TCGA-94-A5I6, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 62.8 years (22,949 days).
Specimen TCGA-94-A5I6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.004d332c-6468-41b2-bbef-4c68c7f8374a.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-94-A5I6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 385 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2e21c24a-1890-4de8-80da-6b052e72b15c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,846; copy number 1: 9,392; copy number 2: 29,855; copy number 3: 12,933; copy number 4: 3,790; copy number 5: 791; copy number 6: 273; copy number 7: 83; copy number 8: 165; copy number 10: 91; copy number 11: 1; copy number 13: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-94-A5I6-01A-21D-A27J-01): tumor purity 0.38, ploidy 2.88, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 493 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:23,801,885–26,575,030, 102 genes (within-gene range 0–2) (broad region; genes not listed).
- chr2:130,755,540–130,776,957, 2 genes: AMER3, CYCSP8.
- chr8:2,935,353–12,418,090, 280 genes (within-gene range 0–1) (broad region; genes not listed).
- chr8:12,719,132–12,719,190, 1 gene: MIR5692A2.
- chr8:12,727,232–12,727,304, 2 genes: MIR3926-1, MIR3926-2.
- chr8:36,784,324–38,063,791, 33 genes (within-gene range 0–1): KCNU1, AC124076.1, TPT1P8, AC090453.1, AC092818.1, SMARCE1P4, AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1.
- chr10:87,500,337–89,645,572, 54 genes: AL355334.2, MIR4678, MINPP1, AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ, RPL7P34, LIPF, NAPGP1, LIPK, KRT8P38, LIPN, RCBTB2P1, LIPM, ANKRD22, PTCD2P2, STAMBPL1, ACTA2-AS1, ACTA2, AL157394.3, FAS, AL157394.2, AL157394.1, MIR4679-2, MIR4679-1, AL513533.1, CH25H, LIPA, IFIT2, AL353751.1, IFIT3, IFIT6P, IFIT1B, IFIT1, IFIT5, SLC16A12, SLC16A12-AS1, PANK1, MIR107.
- chr11:60,056,587–60,098,467, 3 genes (within-gene range 0–2): MS4A3, AP000790.2, MS4A2.
- chr12:65,050,626–65,121,305, 2 genes (within-gene range 0–2): WIF1, RNU6-166P.
- chr17:65,654,914–65,655,395, 1 gene: AC004805.2.
- chr19:6,887,566–6,940,459, 1 gene (within-gene range 0–1): ADGRE1.
- chr19:6,898,299–7,087,968, 12 genes (within-gene range 0–1): AC020895.1, Metazoa_SRP, ADGRE4P, AC025278.1, AC025278.2, AC025278.3, MBD3L2B, MBD3L5, MBD3L4, MBD3L2, MBD3L3, ZNF557.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,422 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:162,486,541–198,222,513, 645 genes, copy number 5–13 (broad region; genes not listed).
- chr4:131,112,748–131,273,348, 2 genes, copy number 5: AC025554.1, RNU6-224P.
- chr5:710,355–45,895,970, 681 genes, copy number 5–13 (broad region; genes not listed).
- chr9:121,444,991–121,520,424, 3 genes, copy number 6 (within-gene range 1–6): GGTA1, RN7SL187P, HMGB1P37.
- chr14:105,736,343–106,301,862, 90 genes, copy number 6 (broad region; genes not listed).
- chr16:14,988,259–14,990,160, 1 gene, copy number 11: AC138932.2.

Autosomal genes at a single copy (total copy number 1): 9,392. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
